Somatic mutation profile of tumor specimen MBCProject_4424_T1_WES (aliquot MBCProject_4424_T1_WES_1) from CMI case MBCProject_4424, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_4424_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1943ef3-0d00-431d-8132-5915b565b42c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4424_SALIVA (Saliva), aliquot MBCProject_4424_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/418ee41f-7127-47ec-9a43-1df5bae10e8d

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 1, RNA 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF21B | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59766970; called by muse, mutect2
- MME | c.2090C>A p.T697N | Missense Mutation (SNP) | VAF 17/492 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs1280378056; called by muse, mutect2
- TREM1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as rs565216476, COSV55149105; called by muse, mutect2
- GCC2 | c.3488C>G p.A1163G | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- NCOR1 | c.3565A>T p.R1189* | Nonsense Mutation (SNP) | VAF 18/237 reads (8%) | called by muse, mutect2
- PDLIM5 | c.17T>A p.V6E | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SETD4 | c.828T>G p.D276E | Missense Mutation (SNP) | VAF 22/457 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- SMCHD1 | c.1760A>T p.D587V | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- UGDH | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- ZNF638 | c.3616A>T p.N1206Y | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2
- AL031777.2 | c.177G>A p.L59= | Silent (SNP) | VAF 9/199 reads (5%) | catalogued as rs1189059173, COSV100587269, COSV61912056; called by muse, mutect2
- FBXO39 | c.792C>T p.H264= | Silent (SNP) | VAF 16/193 reads (8%) | catalogued as rs375399858; called by muse, mutect2
- KCNB2 | c.408C>T p.C136= | Silent (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 6/20 reads (30%) | catalogued as rs190105354; called by muse, varscan2
- HSP90AA4P | n.1530C>A | RNA (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- STT3B | c.1327+179A>T | Intron (SNP) | VAF 9/72 reads (13%) | catalogued as rs1176858420; called by muse, mutect2
